Somatic mutation profile of tumor specimen ALCH-AELX-TTP1-A (aliquot ALCH-AELX-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AELX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.9 years (25,527 days).
Specimen ALCH-AELX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6770220-baea-4aac-9169-b16cb5adf461.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AELX-NB1-A (Blood Derived Normal), aliquot ALCH-AELX-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8faa8753-6ad9-473e-9e1f-63ea748c4a3a

The open-access MAF lists 53 somatic variants for this specimen: 40 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 9, Intron 3, Frame Shift Ins 2, Frame Shift Del 2, Nonsense Mutation 2, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 379/982 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 107/460 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANO7 | c.919G>T p.A307S (on ENST00000274979; = p.A253S on NM_001370694.2) | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.018); catalogued as rs758357636; called by muse, mutect2, varscan2
- ASMT | c.472C>T p.Q158* | Nonsense Mutation (SNP) | VAF 83/516 reads (16%) | catalogued as rs1265068901, COSV67110319; called by muse, mutect2, varscan2
- BNC2 | c.2203G>A p.E735K | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as rs945086064, COSV101033726; called by muse, mutect2, varscan2
- DDX53 | c.1648G>A p.V550I | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs374604625, COSV100029084; called by muse, mutect2
- DNAAF3 | c.1354G>A p.A452T (on ENST00000524407 / NM_001256715.2; = p.A499T on NM_178837.4) | Missense Mutation (SNP) | VAF 46/344 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs546293010, COSV61277795; called by mutect2, varscan2
- F7 | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.869); catalogued as rs149779477; called by muse, mutect2, varscan2
- KPRP | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 68/315 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs765434263, COSV64220950; called by muse, mutect2, varscan2
- LARGE2 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as rs370411213; called by muse, mutect2, varscan2
- NALCN | c.4460C>T p.T1487M | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV99218184; called by muse, mutect2
- NAT8 | c.290T>C p.I97T | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1441300935; called by muse, mutect2
- PRKCE | c.1867G>A p.D623N | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.982); catalogued as rs774629128; called by muse, varscan2
- RAB11FIP4 | c.160G>A p.V54M | Missense Mutation (SNP) | VAF 54/288 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV57931443; called by muse, mutect2, varscan2
- RIC3 | c.283C>A p.L95M | Missense Mutation (SNP) | VAF 26/379 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100112172; called by muse, mutect2
- RXFP1 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs201584410; called by muse, mutect2, varscan2
- SCAP | c.3313C>T p.R1105C | Missense Mutation (SNP) | VAF 52/286 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs779316145; called by muse, mutect2, varscan2
- TTN | c.78971T>C p.V26324A (on ENST00000591111; = p.V18900A on NM_003319.4) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | PolyPhen benign (0.003); catalogued as rs1284864788; called by muse, mutect2, varscan2
- ZFP92 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1556975031; called by muse, mutect2, varscan2
- ZNF512B | c.1804G>A p.G602R | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.982); catalogued as rs1185740713; called by muse, mutect2
- AASDHPPT | c.211G>C p.V71L | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- APPL1 | c.1662A>C p.L554F | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CPEB2 | c.2804C>T p.A935V | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR37 | c.634A>G p.I212V | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIPAP1 | c.2398G>C p.E800Q | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IARS1 | c.995A>G p.D332G | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF11 | c.2408_2411dup p.N805Tfs*13 | Frame Shift Ins (INS) | VAF 22/187 reads (12%) | called by mutect2, pindel, varscan2
- KMT2E | c.4119del p.F1373Lfs*23 | Frame Shift Del (DEL) | VAF 43/173 reads (25%) | called by mutect2, pindel, varscan2
- LNPK | c.317-1G>A p.X106_splice | Splice Site (SNP) | VAF 28/112 reads (25%) | called by muse, varscan2
- MYH1 | c.2581G>C p.E861Q | Missense Mutation (SNP) | VAF 67/405 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLRP13 | c.388G>T p.G130W | Missense Mutation (SNP) | VAF 91/197 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- POLQ | c.7562A>G p.K2521R | Missense Mutation (SNP) | VAF 82/342 reads (24%) | SIFT tolerated (0.85); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- POM121 | c.3471G>T p.Q1157H (on ENST00000434423; = p.Q892H on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/380 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RBM10 | c.1672C>T p.Q558* | Nonsense Mutation (SNP) | VAF 114/588 reads (19%) | called by muse, mutect2, varscan2
- RCOR3 | c.543dup p.E182Rfs*3 | Frame Shift Ins (INS) | VAF 39/176 reads (22%) | called by mutect2, pindel, varscan2
- TAF2 | c.1256G>T p.G419V | Missense Mutation (SNP) | VAF 14/337 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.111); called by muse, mutect2
- TBX5 | c.741G>T p.M247I | Missense Mutation (SNP) | VAF 26/398 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.364); called by muse, mutect2
- UNC13A | c.3836A>G p.D1279G | Missense Mutation (SNP) | VAF 119/236 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- USP42 | c.1764_1776del p.C588* | Frame Shift Del (DEL) | VAF 46/375 reads (12%) | called by mutect2, pindel, varscan2
- WDR62 | c.3666G>C p.R1222S | Missense Mutation (SNP) | VAF 48/686 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2
- BCL9L | c.2550T>G p.S850= | Silent (SNP) | VAF 18/149 reads (12%) | called by muse, varscan2
- KAT6B | c.3514C>T p.L1172= | Silent (SNP) | VAF 52/466 reads (11%) | called by muse, mutect2, varscan2
- KSR1 | c.810C>T p.T270= (on ENST00000644974 / NM_001367810.1; = p.T133= on NM_014238.2) | Silent (SNP) | VAF 41/122 reads (34%) | catalogued as rs1300866425; called by muse, mutect2, varscan2
- MMP14 | c.801G>A p.E267= | Silent (SNP) | VAF 24/161 reads (15%) | called by muse, mutect2, varscan2
- MZF1 | c.1666C>T p.L556= | Silent (SNP) | VAF 49/138 reads (36%) | called by muse, mutect2, varscan2
- NT5DC1 | c.219G>C p.G73= | Silent (SNP) | VAF 38/293 reads (13%) | called by muse, mutect2, varscan2
- PSG1 | c.840C>T p.L280= | Silent (SNP) | VAF 24/658 reads (4%) | called by muse, mutect2
- RABL2A | c.156C>T p.S52= | Silent (SNP) | VAF 37/294 reads (13%) | called by muse, mutect2, varscan2
- SINHCAF | c.528C>T p.I176= | Silent (SNP) | VAF 16/110 reads (15%) | called by muse, varscan2
- KLF11 | c.-29C>T | 5'UTR (SNP) | VAF 41/172 reads (24%) | catalogued as rs1457170889; called by muse, mutect2, varscan2
- LDB3 | c.690-4811C>T | Intron (SNP) | VAF 29/205 reads (14%) | catalogued as rs750606592, COSV53951100; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NKD1 | c.193-1523G>A | Intron (SNP) | VAF 7/95 reads (7%) | catalogued as rs942883476; called by muse, mutect2
- SYCE1 | c.271+26G>A | Intron (SNP) | VAF 24/206 reads (12%) | called by muse, mutect2, varscan2
